Gene-level copy-number profile of tumor specimen TCGA-L9-A7SV-01A from TCGA case TCGA-L9-A7SV, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.3 years (25,298 days).
Specimen TCGA-L9-A7SV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.9586dd0a-8c03-4e80-a563-96b033fe28b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L9-A7SV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/45a73b61-0ee7-438f-8248-23258867ddba

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,671; copy number 2: 19,152; copy number 3: 24,492; copy number 4: 7,563; copy number 5: 2,198; copy number 6: 723; copy number 7: 394; copy number 8: 1,390; copy number 9: 194; copy number 10: 95; copy number 11: 351; copy number 12: 456; copy number 13: 72; copy number 15: 13; copy number 16: 19; copy number 19: 21; copy number 21: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L9-A7SV-01A-11D-A396-01): tumor purity 0.83, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:29,519,731–29,529,974, 1 gene: AC009320.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,996 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–148,288,951, 167 genes, copy number 8 (broad region; genes not listed).
- chr1:149,048,576–166,631,400, 738 genes, copy number 8–16 (broad region; genes not listed).
- chr2:15,166,914–16,432,702, 25 genes, copy number 7–19 (within-gene range 1–19): NBAS, RPS26P18, AC008278.2, DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1.
- chr2:25,377,198–41,731,611, 290 genes, copy number 8–9 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 7–12 (broad region; genes not listed).
- chr10:50,799,409–68,946,847, 173 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr10:72,096,032–75,401,246, 115 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr11:97,657,464–98,131,198, 4 genes, copy number 21: RNA5SP347, LINC02713, AP003730.1, AP001317.1.
- chr17:59,537,359–83,095,122, 774 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
